Somatic mutation profile of tumor specimen TCGA-GL-A59T-01A (aliquot TCGA-GL-A59T-01A-21D-A28G-10) from TCGA case TCGA-GL-A59T, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 46.9 years (17,142 days).
Specimen TCGA-GL-A59T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 679557ca-dbd1-4b19-b8d9-634849b94ef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-A59T-10A (Blood Derived Normal), aliquot TCGA-GL-A59T-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f453fba3-7d40-43a9-96c8-10bf53384a26

The open-access MAF lists 83 somatic variants for this specimen: 59 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 22, Frame Shift Del 6, Nonsense Mutation 5, Splice Region 2, In Frame Del 2, Splice Site 2, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 110/159 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1394653602, COSV59332630; called by muse, mutect2, varscan2
- AHCTF1 | c.2236G>A p.E746K (on ENST00000366508; = p.E720K on NM_015446.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as COSV58247691, COSV58250865; called by muse, mutect2, varscan2
- AP2A2 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV59960634; called by muse, mutect2, varscan2
- CACNA1I | c.2359A>G p.K787E | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60809864; called by muse, mutect2, varscan2
- CEP290 | c.5035G>A p.E1679K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.228); catalogued as COSV58352201; called by muse, mutect2, varscan2
- CEP290 | c.1353T>G p.Y451* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV58352209; called by muse, mutect2, varscan2
- CHD9 | c.4003A>G p.S1335G | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV54610996; called by muse, mutect2, varscan2
- COA4 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV60155724; called by mutect2, varscan2
- DAPK1 | c.3835T>G p.F1279V | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63787877; called by muse, mutect2, varscan2
- EEF1A1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV58549776; called by muse, mutect2, varscan2
- FAM161B | c.1180T>A p.S394T (on ENST00000651776; = p.S331T on NM_152445.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.233); catalogued as COSV54102379; called by muse, mutect2, varscan2
- FAM71E1 | c.643G>A p.A215T (on ENST00000600100 / NM_001308429.2; = p.A199T on NM_138411.3) | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV63096119; called by muse, mutect2, varscan2
- FBXW10 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100111223; called by muse, mutect2, varscan2
- FN1 | c.6739T>C p.S2247P (on ENST00000359671 / NM_001365524.2; = p.S2216P on NM_002026.4) | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV60554245; called by muse, mutect2
- GPC6 | c.962A>C p.E321A | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65513705; called by muse, mutect2, varscan2
- KIF6 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54679363; called by muse, mutect2
- KIN | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV65430725; called by muse, mutect2, varscan2
- KLHL6 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58066745; called by muse, mutect2, varscan2
- LRCH4 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 34/451 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV59643403; called by muse, mutect2
- MPEG1 | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV57091234; called by muse, mutect2, varscan2
- MRPS10 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV50002681; called by muse, mutect2, varscan2
- MUC16 | c.33449G>A p.G11150E | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.148); catalogued as COSV67469587; called by mutect2, varscan2
- NCAPD2 | c.3297T>C p.A1099= | Splice Region (SNP) | VAF 29/124 reads (23%) | catalogued as COSV59699816; called by muse, mutect2, varscan2
- NIT1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV63501769; called by muse, varscan2
- NSD1 | c.811T>G p.L271V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV61777009; called by muse, mutect2, varscan2
- ORC1 | c.1866C>T p.L622= | Splice Region (SNP) | VAF 43/141 reads (30%) | catalogued as rs201622141, COSV65364046; called by muse, mutect2, varscan2
- PADI4 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV64924085; called by muse, mutect2
- PKDREJ | c.5026C>T p.Q1676* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as rs1037446073, COSV53549691; called by muse, mutect2, varscan2
- PLCB4 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV53803523; called by muse, mutect2, varscan2
- PLCE1 | c.2557A>G p.I853V | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV53352576; called by muse, mutect2, varscan2
- PLPPR4 | c.559T>C p.C187R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64566029; called by muse, mutect2, varscan2
- PYGM | c.2074A>T p.T692S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV51217974; called by muse, mutect2, varscan2
- RAB26 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52954647; called by muse, mutect2, varscan2
- RPTOR | c.1139A>C p.Q380P | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV60809489; called by muse, mutect2, varscan2
- RWDD3 | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55721896, COSV55722006; called by mutect2, varscan2
- SDR42E1 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV61094535; called by muse, mutect2, varscan2
- SLC29A1 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57578757, COSV57578859; called by muse, mutect2, varscan2
- SLC37A4 | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV58155610; called by muse, mutect2, varscan2
- SYNE3 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV62079815; called by muse, mutect2
- TCAP | c.110+1G>A p.X37_splice | Splice Site (SNP) | VAF 30/124 reads (24%) | catalogued as COSV54093163; called by muse, mutect2, varscan2
- THBS3 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 38/141 reads (27%) | catalogued as rs775977971, COSV64249519; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV62466792; called by muse, mutect2, varscan2
- TTC30B | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761618327, COSV68809487; called by muse, mutect2, varscan2
- TTC38 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV66844341; called by muse, mutect2, varscan2
- UBA5 | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 156/319 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV53896782; called by muse, varscan2
- ZC3H6 | c.2756G>C p.S919T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV59668029; called by muse, mutect2, varscan2
- ZNF160 | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61999827; called by muse, mutect2, varscan2
- ZNF416 | c.399T>A p.C133* | Nonsense Mutation (SNP) | VAF 59/149 reads (40%) | catalogued as COSV52184710; called by muse, mutect2, varscan2
- ZNF615 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65033578; called by muse, mutect2, varscan2
- ZNF615 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.043); catalogued as COSV65033589; called by muse, mutect2, varscan2
- DNMT3A | c.446del p.A149Gfs*13 | Frame Shift Del (DEL) | VAF 58/150 reads (39%) | called by mutect2, pindel, varscan2
- EFHD1 | c.244_245dup p.E83Rfs*31 | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- IGF2R | c.4718del p.S1573Tfs*9 | Frame Shift Del (DEL) | VAF 69/200 reads (35%) | called by mutect2, varscan2
- KIF13B | c.3207_3213delinsT p.H1070_E1071del | In Frame Del (DEL) | VAF 27/115 reads (23%) | called by pindel, varscan2*
- MYH7B | c.369_373del p.F124Lfs*99 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- NUMA1 | c.321del p.M108* | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- NUP210L | c.2817_2828del p.I940_M943del | In Frame Del (DEL) | VAF 20/68 reads (29%) | called by pindel, varscan2
- OAT | c.97del p.T33Qfs*28 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- SYT2 | c.1093_1094del p.L365Gfs*43 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- ABCC2 | c.984G>A p.L328= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs181542662, COSV64970943; called by muse, mutect2, varscan2
- ANKS1B | c.2241C>T p.S747= | Silent (SNP) | VAF 103/212 reads (49%) | catalogued as COSV61353537; called by muse, mutect2, varscan2
- APP | c.1524C>G p.T508= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV60999124; called by muse, mutect2, varscan2
- BICDL1 | c.426C>T p.L142= | Silent (SNP) | VAF 59/244 reads (24%) | catalogued as rs1308629258, COSV66907940; called by muse, mutect2, varscan2
- CCDC66 | c.1740A>C p.A580= (on ENST00000394672 / NM_001353147.1; = p.A546= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV58304612; called by muse, mutect2
- FAP | c.1542T>C p.D514= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as COSV51862419; called by muse, mutect2, varscan2
- FBXL2 | c.654C>T p.C218= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as COSV52139250; called by muse, mutect2, varscan2
- GATAD1 | c.513A>G p.R171= | Silent (SNP) | VAF 61/126 reads (48%) | catalogued as COSV55319660; called by muse, mutect2, varscan2
- HJURP | c.2070C>G p.G690= | Silent (SNP) | VAF 54/103 reads (52%) | catalogued as COSV64978869, COSV64979786; called by muse, mutect2, varscan2
- HPS1 | c.2007C>T p.A669= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV57268154; called by muse, mutect2, varscan2
- HUWE1 | c.8166T>C p.T2722= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as COSV53347587; called by muse, mutect2, varscan2
- JAK2 | c.3360T>C p.A1120= | Silent (SNP) | VAF 43/56 reads (77%) | catalogued as COSV67614539; called by muse, mutect2, varscan2
- KRT10 | c.609C>T p.I203= | Silent (SNP) | VAF 105/173 reads (61%) | catalogued as rs757208661, COSV54089918; called by muse, mutect2, varscan2
- LARP4 | c.960T>C p.Y320= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as COSV53323023; called by muse, mutect2, varscan2
- NDUFB5 | c.33G>A p.S11= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV52020438; called by muse, mutect2, varscan2
- PAPPA2 | c.393G>A p.G131= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV62779178; called by muse, mutect2
- PARP14 | c.4698A>G p.T1566= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs377210300; called by muse, mutect2, varscan2
- PRCP | c.798A>G p.P266= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs772769194, COSV57289049; called by muse, mutect2, varscan2
- RIPPLY2 | c.204C>T p.A68= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV63762708; called by muse, mutect2
- SLC12A7 | c.246G>T p.V82= | Silent (SNP) | VAF 45/149 reads (30%) | catalogued as rs752912988, COSV53757726; called by muse, mutect2, varscan2
- TBC1D24 | c.1470G>T p.L490= (on ENST00000646147 / NM_001199107.2; = p.L484= on NM_020705.3) | Silent (SNP) | VAF 52/251 reads (21%) | catalogued as COSV53546679; called by muse, mutect2, varscan2
- WWC3 | c.585A>T p.V195= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV66503749; called by muse, mutect2
- C7orf65 | n.140G>A | RNA (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- NSD3 | c.1855+907G>A | Intron (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100388468; called by muse, mutect2, varscan2
